TARGET case TARGET-15-SJMPAL005001 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fef3c279-06ed-4c98-9b6c-70ff123f5439

Demographics
Sex at birth: male; Age at index: 10 years; Vital status: Dead; Days to death: 775 days (2.1 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 10.0 years (3,667 days); Year of diagnosis: 2001; Days to last follow up: 775 days (2.1 years).

Follow-up (1 entry)
- Days to follow up: 775 days (2.1 years); First event: Relapse; Year of follow up: 2003.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 2.2 ×10³/µL.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL005001-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 775
- Protocol: St. Jude
- WBC at Diagnosis: 2.2
- Initial Therapy: ALL
- Karyotype: 47,XY,der(1)add(1)(p36.3)add(1)(q32),t(4;7)(q21;p22),del(9)(p13),der(11)add(11)(p13)add(11)(q21),add(12)(p11.2),add(18)(q23),+mar[12]/46,idem,-der(11)add(11)[4]/47,idem,-der(1)add(1),-der(11)add(11),add(19)(p13.3)[3]/46,XY[6]
- WHO ALAL Classification: T/M
- WHO Dx: T-ALL
- WHO RL1: T/M
- WHO RL2: AML
